Gene-level copy-number profile of tumor specimen TCGA-C5-A8XH-01A from TCGA case TCGA-C5-A8XH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Age at diagnosis: 39.5 years (14,444 days).
Specimen TCGA-C5-A8XH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.fa777d75-36ec-4503-aa97-b9ea658a7f36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A8XH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/875bf94d-eccf-47f6-a409-c3f44150e85f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 691; copy number 2: 15,535; copy number 3: 23,881; copy number 4: 12,281; copy number 5: 3,298; copy number 6: 2,981; copy number 7: 865; copy number 8: 155.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A8XH-01A-11D-A37M-01): tumor purity 0.5, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:23,337,711–26,172,802, 83 genes (broad region; genes not listed).
- chr8:150,584–2,165,552, 48 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,020 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,047,889–63,660,245, 96 genes, copy number 7 (broad region; genes not listed).
- chr1:63,788,721–63,789,304, 1 gene, copy number 7: AL161742.1.
- chr2:196,638,422–201,895,550, 116 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr6:41,905,354–51,410,537, 192 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:142,526,455–143,341,058, 10 genes, copy number 7 (within-gene range 5–7): AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1.
- chr10:86,668,507–88,606,976, 55 genes, copy number 7 (within-gene range 4–7): LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ.
- chr17:65,635,537–66,192,133, 1 gene, copy number 7 (within-gene range 6–7): CEP112.
- chr17:66,197,693–81,034,881, 430 genes, copy number 7 (broad region; genes not listed).
- chr18:47,390–4,455,307, 97 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr21:37,607,373–38,121,345, 1 gene, copy number 7 (within-gene range 4–7): KCNJ6.
- chr21:37,951,425–38,977,774, 21 genes, copy number 7: DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700.

Autosomal genes at a single copy (total copy number 1): 691. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
